Somatic mutation profile of tumor specimen BA2098D (aliquot aq-BA2098D) from BEATAML1.0 case 2414, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.5 years (22,445 days).
Specimen BA2098D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ca00779-1402-40ff-891d-72cad3317f74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2572D (Solid Tissue Normal), aliquot aq-BA2572D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c775f2e5-de18-46fe-8ecc-45fbe8810ba8

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ELFN2 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs912397601; called by muse, mutect2
- SLCO2A1 | c.49A>G p.T17A | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1351005057; called by muse, mutect2, varscan2
- FBXL16 | c.872G>T p.R291L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.14); called by muse, mutect2
- SPOCK1 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- AKT2 | c.639+218G>T | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
